Somatic mutation profile of tumor specimen 0DCXBA from CCDI case PBBMXY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 0.6 years (225 days).
Specimen 0DCXBA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 086434af-b132-46a7-b5b6-1a5c1553dde6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCX8U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0327912e-fb0a-4dc7-8370-cb77dba69f78

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.4028T>A p.V1343E | Missense Mutation (SNP) | VAF 300/890 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, varscan2
- PAAF1 | c.47+35G>A | Intron (SNP) | VAF 232/586 reads (40%) | called by muse, varscan2
